Somatic mutation profile of tumor specimen TCGA-YD-A9TB-06A (aliquot TCGA-YD-A9TB-06A-12D-A401-08) from TCGA case TCGA-YD-A9TB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-YD-A9TB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74ee5b08-f99c-40dd-aac4-b617c4e672ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YD-A9TB-10A (Blood Derived Normal), aliquot TCGA-YD-A9TB-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23b6e639-81e8-42d9-a645-6e5c69d84a19

The open-access MAF lists 404 somatic variants for this specimen: 259 protein-altering or splice-affecting, 135 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 135, Nonsense Mutation 8, RNA 6, Splice Region 4, Intron 3, Splice Site 3, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FLVCR2 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs267606824, CM104787, COSV99471146; ClinVar: pathogenic; called by muse, varscan2
- POU1F1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs104893759, CM031332, CM920587, COSV60155661; ClinVar: pathogenic; called by muse, mutect2
- ADAM18 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55850127; called by muse, mutect2, varscan2
- ADAMTS20 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs867111428, COSV67125755; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs192319648, COSV54439281, COSV54462993; called by muse, mutect2, varscan2
- ADD1 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV99296188; called by muse, mutect2, varscan2
- ADGRG5 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs548356200, COSV100446358; called by muse, mutect2, varscan2
- ADGRL4 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs1452531061, COSV100875744; called by muse, mutect2, varscan2
- ADGRV1 | c.10601C>T p.S3534L | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs778374104, COSV67982263; called by muse, mutect2, varscan2
- AGTR2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs1163188247, COSV64156615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1L1 | c.1948G>A p.G650S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99856618; called by muse, mutect2
- ANK3 | c.8219C>T p.S2740L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV99779002; called by muse, mutect2, varscan2
- ANKRD34B | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV58613372, COSV58613969; called by muse, mutect2, varscan2
- APOB | c.13268C>T p.S4423F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99264523; called by muse, mutect2, varscan2
- ATP2B2 | c.2215C>T p.P739S (on ENST00000352432; = p.P705S on NM_001683.5) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV59503158; called by muse, mutect2, varscan2
- ATXN7 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99894040; called by muse, mutect2, varscan2
- BHMT2 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV99670005; called by muse, mutect2, varscan2
- BRINP3 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100818532; called by muse, mutect2, varscan2
- C3AR1 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV99368253; called by muse, mutect2, varscan2
- CACNA1E | c.1104G>A p.M368I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62384565; called by muse, mutect2, varscan2
- CALCRL | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV101130904; called by muse, mutect2, varscan2
- CCNE1 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV99388241; called by muse, mutect2, varscan2
- CCPG1 | c.673A>T p.I225F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100197013; called by muse, mutect2, varscan2
- CDC25C | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086584; called by muse, mutect2, varscan2
- CDH18 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV56923727; called by muse, mutect2, varscan2
- CDH20 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53016461; called by muse, mutect2, varscan2
- CDKAL1 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99213668, COSV99214558; called by muse, mutect2, varscan2
- CEP164 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV99632803; called by muse, mutect2, varscan2
- CFAP36 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV99701629; called by muse, mutect2, varscan2
- CHST6 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV100178323; called by mutect2, varscan2
- CNTNAP3 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99904419; called by muse, mutect2, varscan2
- COL23A1 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs367931971; called by muse, varscan2
- COL4A1 | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256731483, COSV101011020; called by muse, mutect2, varscan2
- CORIN | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV99903226; called by muse, mutect2
- CRB1 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs778242034, COSV100957750, COSV100958083; called by muse, mutect2, varscan2
- CREBBP | c.6991C>T p.P2331S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); catalogued as COSV52139956; called by muse, mutect2, varscan2
- CSF2RB | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV99453447; called by muse, mutect2
- CUL4B | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV60690937; called by muse, mutect2, varscan2
- CYP7B1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59595742; called by muse, mutect2, varscan2
- DGKD | c.2491C>T p.P831S (on ENST00000264057 / NM_152879.3; = p.P787S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.17); catalogued as rs752631344, COSV99895824; called by muse, mutect2, varscan2
- DKC1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV101053877; called by muse, mutect2
- DLG3 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV99529311; called by muse, mutect2, varscan2
- DNAH11 | c.5179G>A p.E1727K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV100178222; called by muse, mutect2
- DNAH5 | c.12688G>A p.D4230N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99446952; called by muse, mutect2, varscan2
- DNAH5 | c.10495G>A p.E3499K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs148592658, COSV54221637; called by muse, mutect2, varscan2
- DNAH7 | c.11263G>A p.D3755N | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100414443; called by muse, mutect2, varscan2
- DNAH7 | c.8666G>A p.R2889Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752692000, COSV56784652; called by muse, mutect2, varscan2
- DSG1 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as COSV99935728; called by muse, mutect2, varscan2
- EGFLAM | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as rs200790571, COSV59303445, COSV59310220; called by muse, mutect2, varscan2
- EOMES | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99841809; called by muse, mutect2, varscan2
- EPS8 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV55527470, COSV99842842; called by muse, mutect2, varscan2
- ERAP1 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as rs1260377603, COSV99700773; called by muse, mutect2, varscan2
- ERCC5 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99958631; called by muse, mutect2, varscan2
- F5 | c.3089G>A p.R1030Q | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758795781, COSV63121240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM135B | c.1029G>A p.R343= | Splice Region (SNP) | VAF 18/28 reads (64%) | catalogued as COSV99421087, COSV99423694; called by muse, mutect2, varscan2
- FAM149A | c.1321C>T p.P441S (on ENST00000356371 / NM_001367768.2; = p.P150S on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57029258; called by muse, mutect2, varscan2
- FAP | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs762738740, CM145280, COSV51860775; called by muse, mutect2, varscan2
- FITM1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV52824656; called by muse, mutect2, varscan2
- FLG2 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as COSV101165703, COSV101165835; called by muse, mutect2, varscan2
- FMO2 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1353037750, COSV52946559; called by muse, mutect2, varscan2
- FPR3 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV59332732; called by muse, mutect2, varscan2
- FRAS1 | c.4930C>T p.L1644F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs760925105, COSV99349752; called by muse, mutect2, varscan2
- FZR1 | c.468G>A p.K156= | Splice Region (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100553495; called by muse, mutect2, varscan2
- GCM2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101069469; called by muse, mutect2, varscan2
- GCSAML | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100825910; called by muse, mutect2, varscan2
- GIMAP8 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.621); catalogued as COSV56230281; called by muse, mutect2, varscan2
- GJB2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs104894403, CM109516, CM990690, COSV101241478; called by muse, mutect2, varscan2
- GLIPR1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.382); catalogued as rs769346384, COSV99875585; called by muse, mutect2, varscan2
- GLUD2 | c.643A>T p.I215F | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100046681; called by muse, mutect2, varscan2
- GPR158 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); catalogued as rs1179743397, COSV100893016; called by muse, mutect2, varscan2
- GPRASP2 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100176624, COSV59990326; called by muse, mutect2, varscan2
- H1-7 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1212008905, COSV58601927; called by muse, mutect2
- HDAC9 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs1473302983, COSV67776535; called by muse, mutect2
- HHIP | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV56842930; called by muse, mutect2, varscan2
- HIVEP3 | c.4604C>T p.P1535L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99911938; called by muse, mutect2, varscan2
- HOOK2 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1179648222, COSV99317427; called by muse, mutect2
- HRG | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs745904040, COSV99214660; called by muse, mutect2, varscan2
- HROB | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV99809172; called by muse, mutect2, varscan2
- HSD17B2 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs746517736, COSV99556513; called by muse, mutect2, varscan2
- HSP90AA1 | c.1597C>G p.L533V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV99355134; called by muse, mutect2, varscan2
- HTR7 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.619); catalogued as COSV53291439, COSV53294983; called by muse, mutect2, varscan2
- HYDIN | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs377328595; called by muse, mutect2, varscan2
- IL1R1 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99292482; called by muse, mutect2, varscan2
- IL3RA | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs753510585, COSV58430644; called by muse, mutect2, varscan2
- INAVA | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1255478347, COSV100949922; called by muse, mutect2, varscan2
- INHBC | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.565); catalogued as COSV100547966; called by muse, mutect2, varscan2
- KCNH1 | c.1951G>A p.E651K (on ENST00000271751 / NM_172362.3; = p.E624K on NM_002238.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV99658147; called by muse, mutect2, varscan2
- KCNH4 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV99236940; called by muse, mutect2, varscan2
- KCTD7 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.675); catalogued as COSV99299040; called by muse, mutect2, varscan2
- KIAA0232 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100300547; called by muse, mutect2, varscan2
- KIAA1109 | c.12350C>T p.P4117L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99149735; called by muse, mutect2
- KIF14 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as rs757053461, COSV100950711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIR3DL1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58494612; called by muse, mutect2, varscan2
- KIR3DL1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58496755; called by muse, mutect2, varscan2
- KLRC1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as rs1437066323, COSV100760767; called by muse, mutect2, varscan2
- KMT2C | c.7550C>T p.S2517L | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs779659766, COSV100069271; called by muse, mutect2
- KRT5 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs913174272, COSV99357876; called by muse, mutect2, varscan2
- KRT9 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV55853183; called by muse, mutect2
- LCE3E | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.996); catalogued as COSV64231806; called by muse, mutect2, varscan2
- LHFPL4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs762247742, COSV55001576; called by muse, mutect2, varscan2
- LRP12 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99407403; called by muse, mutect2, varscan2
- LRP1B | c.11248C>T p.H3750Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1160114860, COSV67273733; called by muse, mutect2, varscan2
- LRP2 | c.8096G>A p.R2699Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867912144, COSV99787227; called by muse, mutect2, varscan2
- LRRIQ3 | c.1370T>G p.V457G | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV100598576; called by muse, mutect2, varscan2
- MAGEA3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs782715078, COSV100938978, COSV100939016; called by muse, mutect2, varscan2
- MAGEA3 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as rs1556826867, COSV100939015; called by muse, mutect2, varscan2
- MDN1 | c.7876C>T p.L2626F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.373); catalogued as COSV101020971; called by muse, mutect2, varscan2
- MECOM | c.2922G>A p.M974I (on ENST00000468789 / NM_001105078.4; = p.M1162I on NM_004991.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1349991344, COSV99244362; called by muse, mutect2, varscan2
- MECP2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs782576004, COSV100317948; called by muse, mutect2, varscan2
- MEP1A | c.1559G>A p.R520K | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs750488746, COSV100042496; called by muse, mutect2, varscan2
- MFN1 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1021658895, COSV54942844; called by muse, mutect2, varscan2
- MFSD4A | c.1369-1G>A p.X457_splice | Splice Site (SNP) | VAF 29/259 reads (11%) | catalogued as COSV100901476; called by muse, mutect2, varscan2
- MME | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200973878, COSV100852313, COSV64706924; called by muse, mutect2, varscan2
- MNDA | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1185289295, COSV100933292, COSV63740483; called by muse, mutect2, varscan2
- MPRIP | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as rs777866376, COSV57928500; called by muse, mutect2, varscan2
- MUC16 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.022); catalogued as rs866732476, COSV67442189; called by muse, mutect2, varscan2
- MYH1 | c.5216C>T p.S1739F | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV56844579; called by muse, mutect2, varscan2
- MYH11 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs376622843; called by muse, mutect2, varscan2
- MYLK | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100658700; called by muse, mutect2, varscan2
- MYO9B | c.2441C>T p.S814F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68278974; called by muse, mutect2, varscan2
- MYOM2 | c.3042C>T p.P1014= | Splice Region (SNP) | VAF 10/78 reads (13%) | catalogued as rs1237019553, COSV50767523; called by muse, varscan2
- NBEAL2 | c.6937C>T p.H2313Y | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1337718866, COSV99435172; called by muse, mutect2, varscan2
- NDUFS8 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1338114217, COSV99141743; called by muse, mutect2, varscan2
- NEK5 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100839167, COSV100839306; called by muse, mutect2, varscan2
- NEU2 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs761515471, COSV99290497; called by muse, mutect2, varscan2
- NFASC | c.253G>A p.A85T (on ENST00000339876 / NM_001378329.1; = p.A79T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs769904507, COSV58365528; called by muse, mutect2, varscan2
- NFAT5 | c.3889C>T p.P1297S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.115); catalogued as COSV100590624; called by muse, mutect2, varscan2
- NFKB2 | c.662-1G>A p.X221_splice | Splice Site (SNP) | VAF 38/92 reads (41%) | catalogued as COSV99192276; called by muse, mutect2
- NLRP3 | c.1506G>T p.R502S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100275607; called by muse, mutect2, varscan2
- NPAP1 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100274996; called by muse, mutect2, varscan2
- NPHP3 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100446698; called by muse, mutect2, varscan2
- NRG1 | c.998C>T p.S333F (on ENST00000405005 / NM_013964.5; = p.S338F on NM_013956.5) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99828037; called by muse, mutect2, varscan2
- NRIP1 | c.2515C>A p.H839N | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100012435; called by muse, mutect2
- NWD1 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.109); catalogued as rs150409927; called by muse, mutect2, varscan2
- OOEP | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV100949798; called by muse, mutect2, varscan2
- OR10AG1 | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100400005; called by muse, mutect2, varscan2
- OR13A1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100980991; called by muse, mutect2, varscan2
- OR2M4 | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100141061, COSV100141523; called by muse, mutect2, varscan2
- OR51B4 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.076); catalogued as COSV100970940; called by muse, mutect2, varscan2
- OR51I2 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs576821557, COSV58300328; called by muse, mutect2, varscan2
- OR52A5 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs761735684, COSV56616741; called by mutect2, varscan2
- OR52N5 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57698713; called by muse, mutect2, varscan2
- OR5AC2 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62279568; called by muse, mutect2, varscan2
- OR5P2 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV100271249; called by muse, mutect2, varscan2
- OR6C74 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); catalogued as COSV59606230, COSV59606882; called by muse, mutect2, varscan2
- PAPPA2 | c.3308C>T p.S1103L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752126396, COSV62798211; called by muse, mutect2, varscan2
- PAWR | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as COSV60925732; called by muse, mutect2, varscan2
- PBDC1 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV64895747; called by muse, mutect2
- PCDH17 | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1399147992, COSV100931502; called by muse, mutect2, varscan2
- PCDHB16 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV53360342; called by muse, mutect2, varscan2
- PCDHB6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); catalogued as COSV50691822; called by muse, mutect2, varscan2
- PCDHGA7 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99533092, COSV99548612; called by muse, mutect2, varscan2
- PCLO | c.8896C>T p.R2966C | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173009964, COSV61649863; called by muse, mutect2
- PCLO | c.4960G>A p.E1654K | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV100429348; called by muse, mutect2, varscan2
- PCSK5 | c.2281A>C p.S761R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100949724; called by mutect2, varscan2
- PDK3 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 24/159 reads (15%) | catalogued as COSV100998118; called by muse, mutect2, varscan2
- PDS5B | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV59733665; called by muse, mutect2, varscan2
- PEG3 | c.3224G>A p.S1075N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs746102341, COSV99687994; called by muse, mutect2
- PGBD1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV99459904; called by muse, mutect2, varscan2
- PIWIL4 | c.2306A>G p.Y769C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100133149; called by muse, mutect2, varscan2
- PKD1L1 | c.4880C>T p.P1627L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99219015; called by muse, mutect2
- PLCB4 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458167407, COSV53822042; called by muse, mutect2, varscan2
- PLCL1 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1425944906, COSV101406848; called by muse, mutect2, varscan2
- PLEKHA5 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs775103736, COSV100163753; called by muse, mutect2, varscan2
- PLXDC2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65908425; called by muse, mutect2, varscan2
- PNMA5 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs1398116219, COSV62625908; called by muse, mutect2, varscan2
- POSTN | c.2474G>A p.G825E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as COSV65712168; called by muse, mutect2, varscan2
- PPA2 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100049739; called by muse, mutect2, varscan2
- PPIP5K1 | c.4291G>A p.E1431K (on ENST00000396923; = p.E1406K on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as rs1257233742, COSV100288327; called by muse, mutect2, varscan2
- PPP4R4 | c.2606G>A p.R869K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100003700; called by muse, mutect2, varscan2
- PRAMEF2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV53575511; called by muse, mutect2, varscan2
- PRF1 | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV100942559; called by muse, mutect2, varscan2
- PRRC2C | c.4472C>T p.S1491L (on ENST00000367742; = p.S1489L on NM_015172.4) | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100144916; called by muse, mutect2, varscan2
- PRSS38 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs200322609, COSV64541374; called by muse, mutect2, varscan2
- PSG9 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.87); catalogued as COSV99392135; called by muse, mutect2, varscan2
- PSMC1 | c.1269A>C p.K423N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.488); catalogued as COSV99728227; called by muse, mutect2, varscan2
- PTGDR | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143143539, COSV60094486; called by muse, mutect2, varscan2
- PTPN20 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1304726729; called by muse, mutect2, varscan2
- PTPN21 | c.3138G>C p.M1046I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100161678; called by muse, mutect2
- PTX4 | c.1138C>T p.R380C (on ENST00000447419 / NM_001328608.2; = p.R375C on NM_001013658.1) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369527419; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.562); catalogued as COSV99241839; called by muse, mutect2, varscan2
- RAP1GAP | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99264917; called by muse, mutect2, varscan2
- RBBP6 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60504978; called by muse, mutect2, varscan2
- RNPEP | c.1738C>T p.L580F | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs1306926943, COSV99821355; called by muse, mutect2, varscan2
- ROS1 | c.6134C>T p.T2045M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs957947676, COSV100876709, COSV63854059; called by muse, mutect2, varscan2
- RPTOR | c.1400C>A p.A467D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464863648, COSV100155600; called by muse, mutect2, varscan2
- SALL1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs775343492, COSV51758323; called by muse, mutect2, varscan2
- SAMD9 | c.2228G>A p.G743E | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101180104, COSV66073665; called by muse, mutect2, varscan2
- SCN3A | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51813854; called by muse, mutect2
- SEMA4C | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100560809; called by muse, mutect2
- SERPINA7 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs148370308, COSV59666422; called by muse, mutect2, varscan2
- SERPINE1 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99776619; called by muse, mutect2, varscan2
- SHC3 | c.1549G>A p.G517R | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756456873, COSV101011897; called by muse, mutect2, varscan2
- SI | c.3860G>A p.G1287E | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.013); catalogued as COSV100014608; called by muse, mutect2, varscan2
- SIGLEC1 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV99163566; called by muse, varscan2
- SLC22A10 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV60423791; called by muse, mutect2, varscan2
- SLC43A2 | c.424+1G>A p.X142_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100024770; called by muse, mutect2, varscan2
- SLIT2 | c.3589C>T p.L1197F | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99882199; called by muse, mutect2, varscan2
- SLITRK4 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100567228; called by muse, mutect2, varscan2
- SLITRK6 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1156674707, COSV68389908; called by muse, mutect2, varscan2
- SNX8 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs762614982, COSV56129606; called by muse, mutect2, varscan2
- SNX8 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1434970142, COSV99770669; called by muse, mutect2, varscan2
- SORCS3 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63817042; called by muse, mutect2, varscan2
- SPEG | c.9462G>A p.M3154I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1296792557, COSV100403774; called by muse, mutect2, varscan2
- SPHK2 | c.1495C>T p.L499F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99709240; called by muse, mutect2, varscan2
- SPOCK1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99968386; called by muse, mutect2, varscan2
- SPRED1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1345810751, COSV54438084; called by muse, mutect2, varscan2
- SRC | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100658002; called by muse, mutect2
- STAG2 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as COSV54350072; called by muse, mutect2, varscan2
- STK33 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100173817; called by muse, mutect2
- STRC | c.4784G>A p.G1595D | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs746977182, COSV100294492; called by muse, mutect2, varscan2
- SYNE1 | c.718G>A p.E240K (on ENST00000367255 / NM_182961.4; = p.E247K on NM_033071.3) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99557510; called by muse, mutect2, varscan2
- TAF1 | c.473-5C>T | Splice Region (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99335045; called by muse, mutect2, varscan2
- TAL1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV99595939; called by muse, varscan2
- TAS2R40 | c.704G>T p.R235M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101282983; called by muse, mutect2, varscan2
- TBC1D8B | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1156995114, COSV99344071; called by muse, mutect2
- TCEANC | c.62G>A p.R21K (on ENST00000380600 / NM_001297563.2; = p.R51K on NM_152634.4) | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100124605; called by muse, mutect2, varscan2
- TENT5D | c.906G>T p.L302F | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382618, COSV100382937; called by muse, mutect2
- THOC2 | c.4585G>A p.E1529K | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs1353324231, COSV99833008; called by muse, mutect2, varscan2
- TLL1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV50297731; called by muse, mutect2, varscan2
- TMEM207 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100718940; called by muse, mutect2, varscan2
- TNN | c.2458G>A p.V820M | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99511445; called by muse, mutect2, varscan2
- TOP2A | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101396112; called by muse, mutect2, varscan2
- TP63 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs193921145, COSV53197756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPTE2 | c.701C>T p.P234L (on ENST00000400230 / NM_199254.2; = p.P157L on NM_130785.3) | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99689955; called by muse, mutect2, varscan2
- TRAV21 | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); catalogued as rs1249861520; called by muse, mutect2, varscan2
- TRIML2 | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV58720478; called by muse, mutect2, varscan2
- TRIP13 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99386261; called by muse, mutect2, varscan2
- TRPC5 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53289159; called by muse, mutect2, varscan2
- TRPC7 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330057196, COSV61454326; called by muse, mutect2, varscan2
- TTN | c.84484G>A p.G28162R (on ENST00000591111; = p.G20738R on NM_003319.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | PolyPhen possibly damaging (0.859); catalogued as COSV100601316; called by muse, mutect2, varscan2
- TTN | c.70755G>A p.W23585* (on ENST00000591111; = p.W16161* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100601318; called by muse, mutect2, varscan2
- UBQLN3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs201503283, COSV100293465; called by muse, mutect2, varscan2
- UGT2B15 | c.791A>G p.D264G | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100592250; called by muse, mutect2, varscan2
- UGT2B15 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV100592251, COSV57734843; called by muse, mutect2, varscan2
- UGT3A1 | c.1503G>A p.W501* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99954483, COSV99954923; called by muse, mutect2, varscan2
- UGT8 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV100179071; called by muse, mutect2
- USP33 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs771775230, COSV100657050; called by muse, mutect2, varscan2
- USP35 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1188231380, COSV60868856; called by muse, mutect2, varscan2
- VCAN | c.9182C>T p.S3061F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.283); catalogued as COSV54108126; called by muse, mutect2, varscan2
- VIRMA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs113939516, COSV52582182; called by muse, mutect2, varscan2
- VPS53 | c.670C>T p.P224S (on ENST00000571805 / NM_001366253.2; = p.P195S on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52134171; called by muse, mutect2, varscan2
- WDR44 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.036); catalogued as COSV99561359, COSV99561934; called by muse, mutect2
- WNK3 | c.4178C>T p.S1393L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs781830908, COSV63611806, COSV63615042; called by muse, mutect2, varscan2
- XYLB | c.1549C>T p.L517F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV99264064; called by muse, mutect2, varscan2
- ZC4H2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100564841, COSV100565124; called by muse, mutect2, varscan2
- ZKSCAN2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as rs1426684240, COSV60156094; called by muse, mutect2
- ZNF429 | c.1928A>G p.H643R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201515797, COSV100641827; called by muse, mutect2
- ZNF532 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs745979461, COSV60174340; called by muse, mutect2, varscan2
- ZNF594 | c.1607G>T p.S536I | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV101280419; called by muse, mutect2, varscan2
- ZNF800 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV99757736; called by muse, mutect2, varscan2
- ZNF862 | c.1862C>T p.S621L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750627628, COSV99783327; called by muse, varscan2
- ZPLD1 | c.722G>A p.G241E (on ENST00000466937 / NM_001329788.1; = p.G257E on NM_175056.2) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.934); catalogued as COSV60351939; called by muse, mutect2, varscan2
- ZRANB3 | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51508634, COSV99923059; called by muse, mutect2, varscan2
- ZSCAN5B | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1296994632, COSV100627897, COSV62000210; called by muse, mutect2, varscan2
- HECTD4 | c.6785dup p.T2263Nfs*17 | Frame Shift Ins (INS) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- RASSF10 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.053); called by muse, mutect2
- TPTE | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AFF2 | c.3492A>C p.S1164= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV99662743; called by muse, mutect2, varscan2
- AKAP13 | c.6600T>C p.R2200= (on ENST00000394518 / NM_007200.5; = p.R2204= on NM_006738.6) | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100773337; called by muse, mutect2, varscan2
- AMER3 | c.2304C>T p.A768= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs374555063, COSV100366025; called by muse, mutect2, varscan2
- ANK3 | c.2064G>A p.A688= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs747632521, COSV55051747; called by muse, mutect2, varscan2
- ATP8B2 | c.3204C>G p.L1068= (on ENST00000672630; = p.L1035= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as COSV100527801; called by muse, mutect2, varscan2
- BEST2 | c.723C>T p.T241= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1377637719, COSV99244317; called by muse, mutect2, varscan2
- CCR5 | c.96C>T p.L32= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV99433237; called by muse, mutect2, varscan2
- CD164L2 | c.288G>A p.K96= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1367965223, COSV100927584; called by muse, mutect2, varscan2
- CDH10 | c.1266G>A p.L422= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100050620; called by muse, mutect2, varscan2
- CDKL5 | c.1572G>A p.L524= | Silent (SNP) | VAF 75/215 reads (35%) | catalogued as COSV66113206; called by muse, mutect2, varscan2
- CFTR | c.3594G>A p.V1198= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as CS123726, COSV99134694; called by muse, mutect2, varscan2
- CHTF18 | c.2721C>T p.A907= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs755269509, COSV99242501; called by muse, mutect2, varscan2
- CLGN | c.42C>T p.F14= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs1246713031, COSV100346501; called by muse, mutect2, varscan2
- CLK2 | c.42C>T p.S14= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100751834; called by muse, mutect2
- CRAT | c.1878C>T p.L626= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1288902846, COSV100539896; called by muse, mutect2, varscan2
- CSMD2 | c.9468C>T p.F3156= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99587553; called by muse, mutect2, varscan2
- DCDC1 | c.2079G>A p.S693= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs267602843, COSV60854923; called by muse, mutect2, varscan2
- DEPTOR | c.1179G>T p.L393= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV99638180; called by muse, mutect2, varscan2
- DHX34 | c.1173C>T p.I391= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100169373; called by muse, mutect2, varscan2
- DUOX2 | c.3276C>T p.F1092= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1438922273, COSV101199650; called by muse, mutect2, varscan2
- EGFL6 | c.264G>A p.G88= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV63060171; called by muse, mutect2, varscan2
- ELMO1 | c.603C>T p.S201= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100163826; called by muse, mutect2, varscan2
- FADS2 | c.984C>T p.F328= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99608515; called by muse, mutect2, varscan2
- FAM47B | c.1674G>A p.G558= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV61453084; called by muse, mutect2, varscan2
- FAM71D | c.417G>A p.L139= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100315144, COSV61296395; called by muse, mutect2
- FAM83B | c.2217C>T p.S739= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV100174201, COSV100174227; called by muse, mutect2, varscan2
- FANK1 | c.183C>T p.I61= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100904793; called by muse, mutect2, varscan2
- FBF1 | c.2223C>T p.I741= (on ENST00000586717; = p.I755= on NM_001319193.1) | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs905168932, COSV100044883; called by muse, mutect2, varscan2
- FMN2 | c.1188C>T p.S396= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs1430263911, COSV100143993; called by muse, mutect2, varscan2
- FSCB | c.15C>T p.S5= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as COSV100469058, COSV61216365; called by muse, mutect2, varscan2
- FSD2 | c.594G>A p.K198= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as COSV100575066; called by muse, mutect2, varscan2
- GH2 | c.597C>T p.V199= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV60426350; called by muse, mutect2, varscan2
- GPR17 | c.583C>T p.L195= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99760473; called by muse, mutect2
- GRIK2 | c.2055A>G p.V685= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100024360; called by muse, mutect2
- GUCY2C | c.2937C>T p.F979= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs867327497, COSV99663409; called by muse, mutect2, varscan2
- HERC2 | c.10179A>G p.K3393= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV55354723; called by muse, mutect2, varscan2
- HRH2 | c.936C>T p.S312= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99199561; called by muse, mutect2, varscan2
- HYDIN | c.1122C>T p.L374= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs779188404, COSV99862415; called by muse, mutect2, varscan2
- IFI27L1 | c.303C>T p.P101= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs777623103, COSV101267214; called by muse, mutect2, varscan2
- IGFN1 | c.3303C>T p.L1101= (on ENST00000295591 / NM_001367841.1; = p.L3558= on NM_001164586.2) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs777985293, COSV55180360; called by muse, mutect2, varscan2
- IGKV1-9 | c.96C>T p.F32= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as rs752555494; called by muse, mutect2, varscan2
- IQUB | c.1404G>A p.L468= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100226900, COSV61238257; called by muse, mutect2, varscan2
- ITGB3 | c.549G>A p.V183= | Silent (SNP) | VAF 66/128 reads (52%) | catalogued as COSV101457559; called by muse, mutect2, varscan2
- KAT6A | c.1029G>A p.K343= | Silent (SNP) | VAF 128/226 reads (57%) | catalogued as COSV99704667; called by muse, mutect2, varscan2
- KIR3DL3 | c.840C>T p.F280= | Silent (SNP) | VAF 77/150 reads (51%) | catalogued as rs1223733849, COSV52549356; called by muse, mutect2, varscan2
- LAMA1 | c.9108C>T p.F3036= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV101055601; called by muse, mutect2, varscan2
- LELP1 | c.48C>T p.P16= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as COSV64202737; called by muse, mutect2, varscan2
- LGSN | c.1023G>A p.G341= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV65726548; called by muse, mutect2, varscan2
- LMNA | c.1899G>A p.G633= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100738569; called by muse, mutect2, varscan2
- LPCAT4 | c.369C>T p.V123= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV59219591; called by muse, mutect2, varscan2
- LRBA | c.207C>G p.V69= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100841160; called by muse, mutect2, varscan2
- LRFN2 | c.162A>C p.T54= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100599272; called by muse, mutect2, varscan2
- MAGEA1 | c.889C>T p.L297= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV100756624; called by muse, mutect2, varscan2
- MAGEA11 | c.978G>A p.G326= | Silent (SNP) | VAF 109/256 reads (43%) | catalogued as COSV100290431; called by muse, mutect2, varscan2
- MAGEB18 | c.723G>A p.R241= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100305383; called by muse, varscan2
- MAGEH1 | c.520C>T p.L174= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV100746793; called by muse, mutect2, varscan2
- MCM2 | c.606C>T p.F202= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99412943; called by muse, mutect2, varscan2
- MID2 | c.1902C>T p.F634= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1376926695, COSV99464275; called by muse, mutect2, varscan2
- MORC2 | c.1056C>T p.I352= (on ENST00000397641 / NM_001303256.3; = p.I290= on NM_014941.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99309651; called by muse, mutect2, varscan2
- MUC16 | c.14259C>T p.V4753= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV101198937; called by muse, mutect2, varscan2
- MYH8 | c.3204C>T p.S1068= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV101238324; called by muse, mutect2, varscan2
- MYL12B | c.42C>T p.R14= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99410539; called by muse, mutect2, varscan2
- N4BP2 | c.153C>T p.F51= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99788368; called by muse, mutect2, varscan2
- NME8 | c.990G>A p.R330= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV52253991; called by muse, mutect2, varscan2
- NOLC1 | c.336C>T p.V112= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs761590361, COSV100893604; called by muse, mutect2, varscan2
- NYNRIN | c.2347C>T p.L783= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV101230542; called by muse, mutect2, varscan2
- OR14C36 | c.846C>T p.L282= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV100507447; called by muse, mutect2, varscan2
- OR4D11 | c.906G>A p.K302= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57585725, COSV57585770; called by muse, mutect2
- OR4D5 | c.429C>T p.L143= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs377508350; called by muse, mutect2, varscan2
- OR4M1 | c.183C>T p.F61= | Silent (SNP) | VAF 35/271 reads (13%) | catalogued as COSV60060150; called by muse, mutect2, varscan2
- OR52D1 | c.798C>T p.R266= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100495189; called by muse, mutect2, varscan2
- OR6K2 | c.957C>T p.T319= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100656739, COSV62743705; called by muse, mutect2, varscan2
- OR6K3 | c.507C>T p.F169= (on ENST00000368146; = p.F153= on NM_001005327.2) | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV63745527; called by muse, mutect2, varscan2
- OR7G1 | c.94C>T p.L32= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs775736236, COSV99528449; called by muse, mutect2, varscan2
- OR8H3 | c.42C>T p.I14= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs267602991, COSV100538781, COSV57909870; called by muse, mutect2, varscan2
- PAK3 | c.618C>T p.I206= (on ENST00000262836 / NM_001324328.2; = p.I191= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs761722930, COSV53272740; called by muse, mutect2
- PARP3 | c.1443G>A p.Q481= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101290660; called by muse, mutect2, varscan2
- PAX4 | c.933G>A p.P311= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs539092016, COSV58387526; called by muse, mutect2, varscan2
- PBDC1 | c.330G>A p.G110= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100972807; called by muse, mutect2
- PCDHA8 | c.330G>A p.V110= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as rs782251122, COSV100970559; called by muse, mutect2, varscan2
- PCLO | c.2610A>G p.P870= | Silent (SNP) | VAF 109/226 reads (48%) | catalogued as COSV100429350, COSV61675987; called by muse, mutect2, varscan2
- PDAP1 | c.531C>T p.L177= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as COSV99402868; called by muse, mutect2, varscan2
- PDHA2 | c.756C>T p.V252= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV54781101; called by muse, mutect2, varscan2
- PEG3 | c.3102G>A p.K1034= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV55648089; called by muse, mutect2, varscan2
- PI4KB | c.1488G>A p.K496= (on ENST00000368873 / NM_001369623.1; = p.K508= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 87/283 reads (31%) | catalogued as COSV99649435; called by muse, mutect2, varscan2
- PLD5 | c.1542C>T p.F514= (on ENST00000442594; = p.F452= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/279 reads (19%) | catalogued as COSV100139519, COSV59149409; called by muse, mutect2, varscan2
- PPP1R16B | c.1101C>T p.I367= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs780767201, COSV100239173; called by muse, mutect2, varscan2
- PPP1R3A | c.3280T>C p.L1094= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV99492323; called by muse, mutect2, varscan2
- PRICKLE3 | c.1626G>A p.S542= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs782053613, COSV66235314; called by muse, mutect2, varscan2
- PTCHD1 | c.609G>A p.V203= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as rs1456338315, COSV101037392; called by muse, mutect2, varscan2
- PTP4A2 | c.261C>T p.T87= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs1312735773, COSV100685625; called by muse, mutect2, varscan2
- PTPRB | c.3426G>A p.Q1142= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99716445; called by muse, mutect2, varscan2
- RASSF10 | c.1392C>T p.A464= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2
- RSBN1 | c.1482C>T p.F494= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99793011; called by muse, mutect2, varscan2
- SCAF1 | c.265T>C p.L89= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as COSV100862084; called by muse, mutect2, varscan2
- SCN1A | c.2556G>A p.V852= (on ENST00000303395 / NM_001202435.3; = p.V841= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100319778; called by muse, mutect2, varscan2
- SCN5A | c.3834C>T p.I1278= (on ENST00000333535 / NM_198056.3; = p.I1277= on NM_000335.5) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs778600514, COSV61132039; called by muse, mutect2, varscan2
- SEMA3F | c.1404G>A p.V468= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99137273; called by muse, mutect2, varscan2
- SGSM1 | c.1440G>A p.P480= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs371170667; called by muse, mutect2, varscan2
- SHROOM1 | c.2115C>T p.F705= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100166991; called by muse, mutect2
- SLC38A1 | c.438G>A p.G146= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV67063292; called by muse, mutect2, varscan2
- SLC9A4 | c.2160G>A p.R720= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV54829910; called by muse, mutect2, varscan2
- SLCO1B3 | c.531G>A p.G177= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs979933156, COSV99681098; called by muse, mutect2, varscan2
- SLIT2 | c.2868C>T p.V956= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV56573043, COSV99882196; called by muse, mutect2, varscan2
- SPPL2C | c.1086C>T p.F362= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs781558369, COSV61291755; called by muse, mutect2, varscan2
- ST18 | c.1191G>A p.R397= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs1370947820, COSV99388848; called by muse, mutect2, varscan2
- TANC2 | c.5781T>C p.A1927= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101267307; called by muse, mutect2, varscan2
- TAS2R4 | c.358C>T p.L120= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV99924634; called by muse, mutect2, varscan2
- TBC1D9 | c.216C>T p.S72= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1290094463, COSV101121622; called by muse, mutect2, varscan2
- TKTL1 | c.1758C>T p.I586= | Silent (SNP) | VAF 27/222 reads (12%) | catalogued as COSV99473829; called by muse, mutect2, varscan2
- TLL1 | c.510C>T p.F170= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs1342946616, COSV99286034; called by muse, mutect2, varscan2
- TLN2 | c.4804C>T p.L1602= | Silent (SNP) | VAF 61/148 reads (41%) | catalogued as rs756323778, COSV100168439; called by muse, mutect2, varscan2
- TLR7 | c.2538C>T p.S846= | Silent (SNP) | VAF 25/182 reads (14%) | catalogued as COSV66124032; called by muse, mutect2, varscan2
- TM7SF3 | c.564C>T p.S188= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs376318667; called by muse, mutect2, varscan2
- TNIK | c.3177C>T p.N1059= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs767151840, COSV99455966; called by muse, mutect2, varscan2
- TPTE | c.954C>T p.F318= (on ENST00000618007 / NM_199261.4; = p.F300= on NM_199259.4) | Silent (SNP) | VAF 12/402 reads (3%) | catalogued as rs1225910041; called by muse, mutect2
- TRIML1 | c.652C>T p.L218= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs769079880, COSV100205823; called by muse, mutect2, varscan2
- TRPC5 | c.513C>T p.P171= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as COSV99459934; called by muse, mutect2, varscan2
- TSPOAP1 | c.219G>A p.G73= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99270473; called by muse, mutect2, varscan2
- TTN | c.33202C>T p.L11068= (on ENST00000591111; = p.L10141= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100592661, COSV59879935; called by muse, mutect2, varscan2
- TTN | c.11328T>C p.S3776= (on ENST00000591111; = p.S3730= on NM_003319.4) | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100601321; called by muse, mutect2, varscan2
- TTN | c.8166G>A p.Q2722= (on ENST00000591111; = p.Q2676= on NM_003319.4) | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as rs1276074924, COSV100601325; called by muse, mutect2, varscan2
- ULBP2 | c.543C>T p.S181= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs776907728, COSV100951207; called by muse, mutect2, varscan2
- UNC13C | c.1767G>A p.R589= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs750783461, COSV52874990; called by muse, mutect2, varscan2
- USP11 | c.1800C>T p.A600= (on ENST00000218348; = p.A557= on NM_001371072.1) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99510798; called by muse, mutect2
- VIT | c.1053G>A p.T351= (on ENST00000389975 / NM_001177969.1; = p.T366= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as rs1387830382, COSV64895223; called by muse, mutect2, varscan2
- WASHC2C | c.1146C>T p.S382= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1554875621, COSV100313854; called by muse, mutect2, varscan2
- WNK1 | c.993C>T p.I331= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100266692; called by muse, mutect2, varscan2
- ZAP70 | c.546G>A p.Q182= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99385344; called by muse, mutect2, varscan2
- ZDHHC3 | c.147C>T p.I49= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs367543250, COSV56100931; ClinVar: not provided; called by muse, mutect2, varscan2
- ZMYM4 | c.2226T>A p.V742= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100109854; called by muse, mutect2, varscan2
- ZNF230 | c.75G>A p.L25= | Silent (SNP) | VAF 72/134 reads (54%) | catalogued as rs1285690012, COSV101431943; called by muse, mutect2, varscan2
- ZNF292 | c.3306C>T p.V1102= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs148022980; called by muse, mutect2, varscan2
- ZNF485 | c.1188C>T p.G396= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV100700175; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.666C>T p.S222= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as COSV100606009; called by muse, mutect2, varscan2
- CIR1 | c.-2A>C | 5'UTR (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99767156; called by muse, mutect2, varscan2
- DCHS2 | n.2035T>A | RNA (SNP) | VAF 54/143 reads (38%) | catalogued as COSV59718162; called by muse, mutect2, varscan2
- FAM183BP | n.1172G>A | RNA (SNP) | VAF 28/152 reads (18%) | called by muse, mutect2, varscan2
- HERC2P3 | n.60C>T | RNA (SNP) | VAF 5/30 reads (17%) | catalogued as rs774533640; called by mutect2, varscan2
- NACA | c.70+3301C>T | Intron (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100771178; called by muse, mutect2, varscan2
- NMNAT2 | c.86-10925G>A | Intron (SNP) | VAF 13/109 reads (12%) | catalogued as COSV54273086; called by muse, mutect2, varscan2
- NXF5 | n.1046C>T | RNA (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99534187; called by mutect2, varscan2
- SSX9P | n.389G>A | RNA (SNP) | VAF 122/467 reads (26%) | catalogued as rs1214625695; called by muse, mutect2, varscan2
- TMEM183B | n.206C>T | RNA (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- ZNF275 | c.32-769G>A | Intron (SNP) | VAF 48/131 reads (37%) | catalogued as COSV100936192; called by muse, mutect2, varscan2
